Gene-level copy-number profile of tumor specimen C3L-04791-04 from CPTAC case C3L-04791, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 81.4 years (29,749 days).
Specimen C3L-04791-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed7be000-d130-4f67-a234-367ffe15d962.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04791-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/666da455-b66d-4761-b815-d306432bd749

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 632; copy number 1: 9,747; copy number 2: 39,658; copy number 3: 7,476; copy number 4: 563; copy number 5: 709; copy number 6: 28; copy number 7: 1; copy number 8: 89.

Homozygous deletions (total copy number 0; autosomes only): 120 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,203,990–32,552,586, 78 genes (broad region; genes not listed).
- chr9:38,360,427–39,508,885, 33 genes: AL135785.1, ALDH1B1, IGFBPL1, AL390726.5, ARMC8P1, TCEA1P3, GAS2L1P1, VN1R48P, AL390726.1, FAM220BP, AL390726.4, FAM95C, AL390726.3, AL390726.2, SNX18P3, ANKRD18A, FAM201A, YWHABP1, RNU6-765P, AL845311.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr9:39,734,670–39,810,097, 4 genes: RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–3): BX664615.2.
- chr9:66,082,350–66,179,474, 4 genes (within-gene range 0–1): SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 827 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–22,921,500, 713 genes, copy number 5–8 (broad region; genes not listed).
- chr8:71,155,454–71,592,025, 3 genes, copy number 5: AC022858.1, EYA1, TRAPPC2P2.
- chr9:34,634,722–34,681,981, 8 genes, copy number 6: SIGMAR1, GALT, AL162231.3, IL11RA, CCL27, AL162231.4, AL162231.1, AL162231.2.
- chr9:34,702,953–37,090,928, 94 genes, copy number 5–8 (broad region; genes not listed).
- chr9:65,189,995–65,285,209, 4 genes, copy number 6–7: BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr9:66,022,661–66,113,085, 5 genes, copy number 5 (within-gene range 0–5): GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4.

Autosomal genes at a single copy (total copy number 1): 7,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
